Gene-level copy-number profile of tumor specimen TARGET-20-PAKKBK-04A from TARGET case TARGET-20-PAKKBK, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (705 days).
Specimen TARGET-20-PAKKBK-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.807fd5df-545b-5fb3-b90f-52d1323dd1f1.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PAKKBK-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate.
https://portal.gdc.cancer.gov/files/d496df90-f652-45f2-9a2e-dd766f252677

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 526; copy number 1: 2,314; copy number 2: 53,444; copy number 3: 3,898; copy number 4: 53; copy number 5: 26.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes: AL031432.2, RHD, SDHDP6.
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 26 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:35,207,884–35,284,146, 1 gene, copy number 5 (within-gene range 2–5): AC023824.3.
- chr16:35,232,412–35,496,457, 24 genes, copy number 5: FGFR3P5, FRG2JP, RARRES2P6, AGGF1P8, FRG2HP, RARRES2P9, AGGF1P9, C2orf69P4, LINC01566, FRG2GP, AGGF1P4, FRG2IP, RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, AC018558.6, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3.
- chr16:35,504,370–35,506,567, 1 gene, copy number 5: AC018558.1.

Autosomal genes at a single copy (total copy number 1): 2,314. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
